Somatic mutation profile of tumor specimen TCGA-QQ-A8VH-01A (aliquot TCGA-QQ-A8VH-01A-11D-A37C-09) from TCGA case TCGA-QQ-A8VH, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 31.8 years (11,599 days).
Specimen TCGA-QQ-A8VH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23cd99c8-fd19-4781-9e0a-5504edc78e1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A8VH-10A (Blood Derived Normal), aliquot TCGA-QQ-A8VH-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a2e9b8d-eb52-463b-9725-f83c00ef3775

The open-access MAF lists 49 somatic variants for this specimen: 44 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 37, Nonsense Mutation 5, Silent 5, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 37/42 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- NF1 | c.2251G>C p.G751R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1567847681, CS076636, COSV100648504, COSV62198240, COSV62228997; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.487T>A p.Y163N | Missense Mutation (SNP) | VAF 21/26 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACBD5 | c.1174C>A p.H392N (on ENST00000375888 / NM_001352568.1; = p.H383N on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV101022708; called by muse, mutect2, varscan2
- ALDH1A3 | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320292, COSV100320804; called by muse, mutect2, varscan2
- APC | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); catalogued as rs768233232, CM023006, COSV57331228, COSV99970911; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP30 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs202221316, COSV63517278; called by muse, mutect2, varscan2
- DCAF11 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100386937, COSV58110004; called by muse, mutect2, varscan2
- DNAH7 | c.3433G>T p.V1145F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100418131; called by muse, mutect2, varscan2
- FAM47C | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.307); catalogued as COSV63725008; called by muse, varscan2
- FAM47C | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV63723484, COSV63730918; called by muse, varscan2
- FLNA | c.5014A>G p.I1672V (on ENST00000369850 / NM_001110556.2; = p.I1664V on NM_001456.3) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV100775380; called by muse, mutect2, varscan2
- GPAT4 | c.462G>C p.Q154H | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101214166, COSV67842170; called by muse, mutect2, varscan2
- IFIH1 | c.1529G>A p.C510Y | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99718966; called by muse, mutect2, varscan2
- KCNH1 | c.1536C>A p.Y512* (on ENST00000271751 / NM_172362.3; = p.Y485* on NM_002238.4) | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as COSV99662004; called by muse, mutect2, varscan2
- KCNH8 | c.967G>T p.V323L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100111211, COSV60457729; called by muse, mutect2, varscan2
- KIT | c.2716T>C p.C906R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99855585; called by muse, mutect2, varscan2
- LHCGR | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.529); catalogued as COSV99684350; called by muse, mutect2, varscan2
- MAGED2 | c.1141A>C p.M381L | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV99514815; called by muse, mutect2
- MAPK15 | c.664T>A p.S222T | Missense Mutation (SNP) | VAF 101/116 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139010308; called by muse, mutect2, varscan2
- PARN | c.13A>T p.R5W | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99902507; called by muse, mutect2
- PLXNA4 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58105481, COSV58133956; called by muse, mutect2
- PTH2R | c.807C>G p.F269L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV55919448, COSV99783014; called by muse, mutect2
- PTPRU | c.2558C>T p.S853F | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.822); catalogued as COSV60525779; called by muse, mutect2, varscan2
- QRICH2 | c.1571T>A p.L524* | Nonsense Mutation (SNP) | VAF 42/91 reads (46%) | catalogued as COSV99429855; called by muse, mutect2, varscan2
- RASSF9 | c.820A>T p.K274* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100771639; called by muse, mutect2, varscan2
- RSF1 | c.4204G>A p.A1402T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.123); catalogued as rs928234973, COSV100408103; called by muse, mutect2, varscan2
- SDK1 | c.4047C>G p.Y1349* | Nonsense Mutation (SNP) | VAF 33/71 reads (46%) | catalogued as COSV101270009; called by muse, mutect2, varscan2
- SHPRH | c.2806C>G p.R936G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51604800, COSV99262492, COSV99262842; called by muse, mutect2, varscan2
- SLC4A4 | c.2443-1G>A p.X815_splice (on ENST00000264485 / NM_001098484.3; = p.X771_splice on NM_003759.4) | Splice Site (SNP) | VAF 34/71 reads (48%) | catalogued as COSV99143469; called by muse, mutect2, varscan2
- SRCAP | c.5779A>G p.T1927A | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV99351633, COSV99351937; called by muse, mutect2
- STKLD1 | c.1974C>G p.F658L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.067); catalogued as COSV100905786; called by muse, varscan2
- SYNGAP1 | c.2690C>T p.S897L | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.636); catalogued as COSV99539205; called by muse, mutect2, varscan2
- TDRD6 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60174450; called by muse, mutect2
- TECTA | c.5470G>A p.G1824S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751680641, COSV99881890; called by muse, mutect2, varscan2
- TMEM87B | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 5/90 reads (6%) | catalogued as COSV99314758; called by muse, mutect2
- TNFRSF21 | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV99730371; called by muse, mutect2, varscan2
- TOP2B | c.2172G>C p.L724F (on ENST00000264331 / NM_001330700.2; = p.L719F on NM_001068.3) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99980482; called by muse, mutect2
- ZBTB12 | c.762C>G p.S254R | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs753644043, COSV100977061; called by muse, mutect2, varscan2
- ZC4H2 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as COSV100565301; called by muse, mutect2, varscan2
- ZDHHC13 | c.1115C>A p.A372E | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV101240138; called by muse, mutect2, varscan2
- ZNF568 | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100451477; called by muse, mutect2, varscan2
- AGBL2 | c.1631+1del p.X544_splice | Splice Site (DEL) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- CACNA1C | c.6439A>G p.S2147G (on ENST00000399634 / NM_001167625.1; = p.S2076G on NM_000719.7) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2
- CARMIL1 | c.1302A>C p.T434= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as rs1213739015, COSV100279010; called by muse, mutect2
- IGFBP5 | c.277C>T p.L93= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV99288901, COSV99289114; called by muse, mutect2, varscan2
- IGKV6D-41 | c.237C>G p.P79= | Silent (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- OPN4 | c.508C>T p.L170= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV54116540; called by muse, mutect2, varscan2
- PSG11 | c.696C>A p.T232= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV60457090; called by muse, mutect2
